Somatic mutation profile of cancer-model specimen HCM-CSHL-0158-C20-85A (3D Organoid; aliquot HCM-CSHL-0158-C20-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0158-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.2 years (20,877 days).
Specimen HCM-CSHL-0158-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8518cc8-4bd4-4d61-ac7a-63adafe38a5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0158-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0158-C20-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13848e40-6cb3-4059-9ee5-a69e0244fdb9

The open-access MAF lists 122 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 23, Intron 7, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 139/408 reads (34%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 241/243 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 392/725 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254014649; called by muse, mutect2, varscan2
- ABCA9 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 232/365 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs547831027, COSV60619833; called by muse, mutect2, varscan2
- ADAMTS5 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865877973, COSV53182560, COSV99538047; called by muse, mutect2, varscan2
- ADAP1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 85/583 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs748582543, COSV99763467; called by muse, mutect2, varscan2
- ADCY6 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1312450652, COSV57166651; called by muse, mutect2, varscan2
- AHNAK2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 218/520 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200854519; called by muse, mutect2, varscan2
- ASTN2 | c.3989G>A p.R1330Q (on ENST00000313400 / NM_001365069.1; = p.R1279Q on NM_014010.5) | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.978); catalogued as rs367824366; called by muse, mutect2, varscan2
- BORCS6 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 239/488 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1428369985; called by muse, mutect2, varscan2
- C11orf24 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs147283671; called by muse, mutect2, varscan2
- CCNYL1 | c.290C>T p.T97M (on ENST00000295414 / NM_001330218.2; = p.T27M on NM_152523.2) | Missense Mutation (SNP) | VAF 78/134 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.775); catalogued as rs542007393; called by muse, mutect2, varscan2
- CDH4 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340686331; called by muse, mutect2, varscan2
- CDH6 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 314/700 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs772276938; called by muse, mutect2, varscan2
- CDON | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 221/643 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs769676286, CM160061, COSV54997908; called by muse, mutect2, varscan2
- COL23A1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs776511487; called by muse, mutect2, varscan2
- CROCC | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as rs761081353, COSV65015293; called by muse, mutect2, varscan2
- CSRNP3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 329/506 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs374214581; called by muse, mutect2, varscan2
- DENND2A | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 341/570 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs764039930, COSV52054933, COSV99327036; called by muse, mutect2, varscan2
- EID1 | c.560_561del p.E187Vfs*6 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as rs750781501; called by pindel, varscan2
- EIF2B5 | c.746G>A p.R249Q (on ENST00000647909; = p.R241Q on NM_003907.3) | Missense Mutation (SNP) | VAF 185/576 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56606505; called by muse, mutect2, varscan2
- EYS | c.4805C>T p.A1602V | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as rs1353073807; called by muse, mutect2, varscan2
- FGD5 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs368016397; called by muse, mutect2, varscan2
- GPR132 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 249/528 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs573418373; called by muse, mutect2, varscan2
- IFITM5 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs376963969; ClinVar: uncertain significance; called by muse, mutect2
- IGSF9 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); catalogued as rs143847211; called by muse, mutect2, varscan2
- IL26 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs778481071, COSV57488466; called by muse, mutect2, varscan2
- INAVA | c.67dup p.E23Gfs*11 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | catalogued as rs750421792; called by mutect2, pindel, varscan2
- ITGAD | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs767511529, COSV66758313; called by muse, mutect2, varscan2
- KCNA5 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 295/436 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1020769441, COSV99363713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM4B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs143993914; called by muse, mutect2, varscan2
- KHDC1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.984); catalogued as rs369792369; called by muse, mutect2
- KIAA0513 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1366593033, COSV50745281; called by muse, mutect2, varscan2
- KIF1A | c.1778G>T p.R593L | Missense Mutation (SNP) | VAF 206/330 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57495082; called by muse, mutect2, varscan2
- KLHL32 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 127/188 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs752627797, COSV65111334; called by muse, mutect2, varscan2
- KLRD1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755827000, COSV60273399; called by muse, mutect2, varscan2
- LCE2B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 286/597 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs759523297, COSV100909340, COSV64228104; called by muse, mutect2, varscan2
- LRP2 | c.3667+1G>A p.X1223_splice | Splice Site (SNP) | VAF 84/276 reads (30%) | catalogued as rs752197557, COSV55546404; called by muse, mutect2, varscan2
- MARCHF4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1214830803, COSV56102656; called by muse, mutect2, varscan2
- MRPL47 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201911825; called by muse, mutect2, varscan2
- NMBR | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143952823, COSV104382245, COSV99237157; called by muse, mutect2
- OTX1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV56995651; called by muse, mutect2, varscan2
- PCDHGB5 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 455/883 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775633916; called by muse, mutect2, varscan2
- PERM1 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 247/514 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1160965040, COSV100379051; called by muse, mutect2, varscan2
- PHKA2 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 285/286 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs758012915; called by muse, mutect2, varscan2
- PTPRN | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 178/284 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772936871, COSV55348561, COSV99834068; called by muse, mutect2, varscan2
- RYR2 | c.10415G>A p.R3472Q | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1460432238, COSV63703137; called by muse, mutect2, varscan2
- SEMA6B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs753670884; called by muse, mutect2, varscan2
- SERPINH1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 397/830 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs776140347; called by muse, mutect2, varscan2
- SLC16A7 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.358); catalogued as rs141650282; called by muse, mutect2, varscan2
- SLC4A11 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 206/1437 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs764537629, COSV66263742; called by muse, mutect2, varscan2
- SPG7 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 177/357 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376397768; called by muse, mutect2, varscan2
- SYN1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1171134481, COSV55980351; called by muse, mutect2, varscan2
- SYT7 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 93/457 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99801903; called by muse, mutect2, varscan2
- TBC1D9 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 155/239 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757700003, COSV65932265; called by muse, mutect2, varscan2
- TIAM1 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs529598323, COSV54543783; called by muse, mutect2, varscan2
- TRPM2 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs777861519, COSV55966341; called by muse, mutect2, varscan2
- TTN | c.20192G>A p.R6731Q (on ENST00000591111; = p.R5804Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | PolyPhen possibly damaging (0.67); catalogued as rs148072021, COSV59923807, COSV59975784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.11360G>T p.S3787I (on ENST00000591111; = p.S3741I on NM_003319.4) | Missense Mutation (SNP) | VAF 133/223 reads (60%) | catalogued as COSV59950405; called by muse, mutect2, varscan2
- ULK2 | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141459584; called by muse, mutect2, varscan2
- VWA1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1280014527; called by muse, mutect2, varscan2
- ABCD1 | c.2165A>G p.E722G | Missense Mutation (SNP) | VAF 162/163 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- APC | c.3081_3082del p.Y1027* | Frame Shift Del (DEL) | VAF 122/272 reads (45%) | called by pindel, varscan2
- BCL9 | c.3838C>T p.Q1280* | Nonsense Mutation (SNP) | VAF 216/441 reads (49%) | called by muse, mutect2, varscan2
- BRINP2 | c.2038del p.I680Lfs*21 | Frame Shift Del (DEL) | VAF 150/371 reads (40%) | called by mutect2, pindel, varscan2
- CENPO | c.594+2T>A p.X198_splice | Splice Site (SNP) | VAF 84/128 reads (66%) | called by muse, varscan2
- CLDN11 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 143/416 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- DHX40 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ECEL1 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 353/1279 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ELF3 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 341/700 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBXL19 | c.526T>G p.L176V | Missense Mutation (SNP) | VAF 278/564 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FLG | c.9794G>A p.G3265E | Missense Mutation (SNP) | VAF 37/857 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- KCNQ4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 335/739 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MPO | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 393/619 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PCDHGB5 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PCNT | c.4368G>C p.Q1456H | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PKHD1L1 | c.7758C>A p.Y2586* | Nonsense Mutation (SNP) | VAF 57/536 reads (11%) | called by muse, mutect2, varscan2
- PRKDC | c.10686G>T p.L3562F | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PXDN | c.3784C>A p.L1262M | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAG1 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 260/528 reads (49%) | called by muse, mutect2, varscan2
- RGS21 | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD6 | c.1343G>A p.S448N (on ENST00000219315 / NM_001160305.4; = p.S424N on NM_024860.3) | Missense Mutation (SNP) | VAF 152/311 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SHISA6 | c.1342C>A p.P448T (on ENST00000409168 / NM_001173461.1; = p.P499T on NM_207386.4) | Missense Mutation (SNP) | VAF 151/292 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A11 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAB2 | c.5230C>A p.L1744I | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TBC1D17 | c.1367A>G p.Q456R | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TNRC6B | c.1823del p.L608* | Frame Shift Del (DEL) | VAF 104/276 reads (38%) | called by mutect2, pindel, varscan2
- WFDC9 | c.79A>G p.N27D | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF334 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- A4GALT | c.1041G>A p.E347= | Silent (SNP) | VAF 137/265 reads (52%) | catalogued as rs761140271; called by muse, mutect2, varscan2
- AHNAK2 | c.2187C>T p.S729= | Silent (SNP) | VAF 399/812 reads (49%) | catalogued as rs568401227, COSV60912601; called by muse, mutect2, varscan2
- ARHGAP15 | c.84C>A p.I28= | Silent (SNP) | VAF 55/156 reads (35%) | called by muse, mutect2, varscan2
- ASRGL1 | c.744G>A p.A248= | Silent (SNP) | VAF 270/554 reads (49%) | catalogued as rs374349770; called by muse, mutect2, varscan2
- COL20A1 | c.87C>T p.S29= | Silent (SNP) | VAF 147/429 reads (34%) | catalogued as rs761610149; called by muse, mutect2, varscan2
- DGKB | c.1356A>G p.G452= | Silent (SNP) | VAF 90/156 reads (58%) | called by muse, mutect2, varscan2
- DLG2 | c.1641C>T p.Y547= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs183726641, COSV54646141; called by muse, mutect2, varscan2
- EPHA8 | c.1882C>A p.R628= | Silent (SNP) | VAF 156/309 reads (50%) | catalogued as COSV99031691; called by muse, mutect2, varscan2
- FGF23 | c.330G>A p.P110= | Silent (SNP) | VAF 497/765 reads (65%) | catalogued as rs1202091925, COSV52976226; called by muse, mutect2, varscan2
- JPH2 | c.1461G>A p.P487= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs781613132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDR | c.1287C>A p.I429= | Silent (SNP) | VAF 96/405 reads (24%) | called by muse, mutect2, varscan2
- LMNA | c.480C>T p.G160= | Silent (SNP) | VAF 251/548 reads (46%) | catalogued as rs758848135, COSV100738628; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAB21L1 | c.171C>T p.N57= | Silent (SNP) | VAF 111/485 reads (23%) | called by muse, mutect2, varscan2
- MS4A4E | c.372C>T p.G124= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs1395825192; called by muse, mutect2, varscan2
- MYLK3 | c.141A>G p.T47= | Silent (SNP) | VAF 93/438 reads (21%) | called by muse, mutect2, varscan2
- OR11H4 | c.663T>C p.S221= | Silent (SNP) | VAF 57/103 reads (55%) | catalogued as rs1233187092; called by muse, mutect2, varscan2
- OR2J3 | c.720G>A p.V240= | Silent (SNP) | VAF 74/221 reads (33%) | called by muse, mutect2, varscan2
- OR5D18 | c.660G>A p.A220= | Silent (SNP) | VAF 106/473 reads (22%) | catalogued as rs779827741, COSV61737938, COSV61738052; called by muse, mutect2, varscan2
- PTPRJ | c.1701C>T p.S567= | Silent (SNP) | VAF 84/418 reads (20%) | catalogued as rs142074473; called by muse, mutect2, varscan2
- RGS7BP | c.138C>T p.T46= | Silent (SNP) | VAF 140/285 reads (49%) | called by muse, mutect2, varscan2
- SHANK1 | c.1449C>T p.S483= | Silent (SNP) | VAF 66/310 reads (21%) | catalogued as rs746142104; called by muse, mutect2, varscan2
- SVOPL | c.825T>C p.A275= (on ENST00000419765; = p.A123= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/282 reads (11%) | called by muse, mutect2, varscan2
- TBCB | c.429C>T p.A143= | Silent (SNP) | VAF 166/359 reads (46%) | called by muse, mutect2, varscan2
- BPTF | c.8640-747G>A | Intron (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- C3orf35 | chr3:37417698 G>A | 3'Flank (SNP) | VAF 53/101 reads (52%) | catalogued as rs554690420; called by muse, mutect2, varscan2
- DDX31 | c.2141-17G>A | Intron (SNP) | VAF 213/437 reads (49%) | catalogued as rs572017150; called by muse, mutect2, varscan2
- FYN | c.862+533G>A | Intron (SNP) | VAF 100/150 reads (67%) | catalogued as rs777800541; called by muse, mutect2, varscan2
- PCLO | c.14791+9C>T | Intron (SNP) | VAF 311/567 reads (55%) | catalogued as COSV61616495; called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+43G>A | Intron (SNP) | VAF 58/122 reads (48%) | catalogued as COSV52990929; called by muse, mutect2, varscan2
- RGP1 | c.-107C>A | 5'UTR (SNP) | VAF 155/408 reads (38%) | called by muse, varscan2
- SNAI2 | c.-23C>T | 5'UTR (SNP) | VAF 133/1137 reads (12%) | called by muse, mutect2, varscan2
- STXBP2 | c.578+26C>T | Intron (SNP) | VAF 123/266 reads (46%) | catalogued as rs747100746; called by muse, mutect2, varscan2
- STXBP2 | c.1452+37C>T | Intron (SNP) | VAF 120/538 reads (22%) | catalogued as rs780957276; called by muse, mutect2, varscan2
